Surgical pathology report (de-identified scan), TCGA case TCGA-32-1977, project TCGA-GBM (Glioblastoma Multiforme), tissue source site St. Joseph's Hospital (AZ), specimen TCGA-32-1977-01A (Primary Tumor).

NEUROPATHOLOGY REPORT

SPECIMEN SOURCE:

1. Right frontal brain tumor
2. Right frontal brain tumor

GBM [REDACTED]
CONTROL [REDACTED]

CLINICAL DIAGNOSIS:

Right frontal brain tumor

TCGA-32-1977

GROSS DESCRIPTION:

1. Received fresh for frozen section labeled with the patient's name and "right frontal brain tumor" are multiple pink-tan soft tissue fragments aggregating to 0.9 x 0.4 x 0.3 cm. A smear is performed with the remainder frozen on one chuck.

FROZEN SECTION DIAGNOSIS:

GLIOBLASTOMA. [REDACTED]

The specimen is subsequently entirely resubmitted in one cassette for permanent sections.

2. Received in formalin labeled with the patient's name and "right frontal brain tumor" are multiple white hemorrhagic soft tissue fragments aggregating to 4.0 x 3.0 x 2.0 cm. In addition, there is a separate portion of pink-tan membranous soft tissue consistent with dura measuring 3.5 x 3.0 x 0.1 cm. There is a small 0.5 cm thickened area of the dura. Representative sections (approximately 20%) are submitted as follows:

- A) Tumor and separate portion of dura
- B) Tumor

MICROSCOPIC DESCRIPTION:

1, 2. Sections demonstrate a markedly hypercellular glial neoplasm. The tumor is composed of cells resembling mildly to moderately atypical astrocytes with round to oval nuclei. Scattered mitotic figures are seen. There is a striking pattern of microvascular proliferation and large areas of necrosis, as well as smaller areas of pseudopalisading necrosis are seen. Although the nuclei are

MICROSCOPIC DESCRIPTION:

round and some demonstrate few processes, definite oligodendroglioma differentiation is not seen.

DIAGNOSIS:

(PROVISIONAL)

- 1, 2. RIGHT FRONTAL BRAIN TUMOR, BIOPSY AND RESECTION:
GLIOBLASTOMA (ASTROCYTOMA GRADE IV), PENDING ADDITIONAL STUDIES.

ADDENDUM NEUROPATHOLOGY REPORT

ADDENDUM DISCUSSION:

Overall, <10% of the tumor demonstrate immunoreactivity for MGMT.

ADDENDUM DIAGNOSIS:

- 1, 2. RIGHT FRONTAL BRAIN TUMOR, BIOPSY AND RESECTION:
GLIOBLASTOMA (ASTROCYTOMA GRADE IV).
- MGMT EXPRESSION <10%.

Source: NCI Genomic Data Commons file 0998cd0d-1f5a-4de0-86a4-cb2caf1b561e (TCGA-32-1977.7BA4D37C-DF8E-4CF2-B0E9-0A8CEB8378E0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).